Somatic mutation profile of tumor specimen TCGA-QR-A6GX-01A (aliquot TCGA-QR-A6GX-01A-11D-A35D-08) from TCGA case TCGA-QR-A6GX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 28.9 years (10,548 days).
Specimen TCGA-QR-A6GX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffc7caa9-ad9f-453f-ad03-5de38f8ba810.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6GX-10A (Blood Derived Normal), aliquot TCGA-QR-A6GX-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d454813-e597-42d6-a243-7aef5f20cc29

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.7498A>T p.I2500F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1057519916, COSV63869574; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1600G>A p.A534T (on ENST00000404938 / NM_001163941.2; = p.A89T on NM_178559.6) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs745873483, COSV51704716; called by muse, mutect2, varscan2
- COL5A3 | c.2842C>T p.L948F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1191734306; called by muse, mutect2, varscan2
- DPEP1 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV104376541; called by muse, mutect2, varscan2
- TSPOAP1 | c.4628A>G p.N1543S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs369628618; called by muse, mutect2, varscan2
- AFAP1L1 | c.119T>C p.I40T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- GAS2L2 | c.1631A>G p.D544G | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- GMPR | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENM1 | c.5471A>C p.D1824A | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ERICH6 | c.1791G>A p.L597= | Silent (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- SCAF8 | c.936A>C p.L312= | Silent (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2
- ZNF319 | c.54A>T p.P18= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1317001998; called by muse, mutect2, varscan2
